Surgical pathology report (de-identified scan), TCGA case TCGA-IR-A3LI, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site Memorial Sloan Kettering, specimen TCGA-IR-A3LI-01A (Primary Tumor).

[page 1 of 3]
Specimens Submitted:

- 1: SP: Right adnexal mass (fa) (
- 2: SP: Left adnexal mass (
- 3: SP: Cul-de-sac metastases
- 4: SP: Posterior peritonectomy
- 5: SP: Uterus, cervix, partial parametria (
- 6: SP: Bladder peritoneum)
- 7: SP: Left external iliac lymph node
- 8: SP: Left hypogastric lymph nodes (
- 9: SP: Left parametrial lymph nodes (
- 10: SP: Left obturator lymph nodes
- 11: SP: Left common iliac lymph nodes
- 12: SP: Right external iliac lymph nodes (
- 13: SP: Distal right external iliac lymph node
- 14: SP: Right hypogastric lymph node--
- 15: SP: Right obturator lymph node
- 16: SP: Right para-aortic lymph node
- 17: SP: Left para-aortic lymph node
- 18: SP: Omentectomy

DIAGNOSIS:

- 1) ADNEXA, RIGHT, MASS; EXCISION:
- METASTATIC ADENOCARCINOMA.
- 2) ADNEXA, LEFT, MASS; EXCISION:
- METASTATIC ADENOCARCINOMA.
- 3) SOFT TISSUE, CUL-DE-SAC; BIOPSY:
- METASTATIC ADENOCARCINOMA.
- 4) PERITONEUM, POSTERIOR; BIOPSY:
- REACTIVE PAPILLARY MESOTHELIAL PROLIFERATION.
- 5) UTERUS, CERVIX; HYSTERECTOMY:
- INVASIVE ADENOCARCINOMA OF UTERINE CERVIX, MODERATELY DIFFERENTIATED.

** Continued on next page **

ICD-0-3

adenocarcinoma, endocervical type

8384/3

Site: cervix, NOS C53.9

hw
12/20/11

[page 2 of 3]
-
- THE MAXIMAL THICKNESS OF THE CERVICAL STROMAL INVASION IS 12 MM.
- THE THICKNESS OF THE CERVIX IN THE AREA OF MAXIMAL TUMOR INVASION IS 12 MM.
- NO EVIDENCE OF TUMOR MULTICENTRICITY IS IDENTIFIED.
- VASCULAR INVASION IS PRESENT.
- NO VAGINAL EXTENSION IS IDENTIFIED.
- THE TUMOR EXTENDS INTO THE LOWER UTERINE SEGMENT (MUCOSA AND STROMA).
- THE RIGHT AND LEFT PARACERVICAL SOFT TISSUE MARGINS ARE INVOLVED BY TUMOR.
- THE ENDOMETRIUM IS INACTIVE.
- THE MYOMETRIUM SHOWS LEIOMYOMATA.

NOTE: ER, PR VIMENTIN, P16 AND M-CEA IMMUNOHISTOCHEMICAL STAINS WERE PERFORMED ON REPRESENTATIVE SECTIONS OF TUMOR FROM THE ADNEXAL MASS, CERVIX AND LOWER UTERINE SEGMENT. THE RESULTS ARE GENERALLY CONCORDANT AND SUPPORT AN ENDOCERVICAL PRIMARY. P16 AND M-CEA ARE POSITIVE WHILE PR AND VIMENTIN ARE NEGATIVE. SECTIONS FROM THE CERVIX AND LOWER UTERINE SEGMENT SHOW FOCAL ER EXPRESSION.

- 6) BLADDER, PERITONEUM; BIOPSY:
- BENIGN FIBROADIPOSE TISSUE.
- 7) LYMPH NODE, LEFT EXTERNAL ILIAC; BIOPSY:
- ONE BENIGN LYMPH NODE (0/1).
- 8) LYMPH NODE, LEFT HYPOGASTRIC; EXCISION:
- FIVE BENIGN LYMPH NODES (0/5).
- 9) LYMPH NODE, LEFT PARAMETRIAL; EXCISION:
- BENIGN FIBROADIPOSE TISSUE.
- 10) LYMPH NODE, LEFT OBTURATOR; EXCISION:
- METASTATIC ADENOCARCINOMA TO ONE OF SIX LYMPH NODES (1/6).

NOTE: MIB-1 AND P16 IMMUNOSTAINS SUPPORT THE DIAGNOSIS.

- 11) LYMPH NODE, LEFT COMMON ILIAC; EXCISION:
- BENIGN FIBROADIPOSE TISSUE.
- 12) LYMPH NODE, RIGHT EXTERNAL ILIAC; BIOPSY:
- ONE BENIGN LYMPH NODE (0/1).
- 13) LYMPH NODE, RIGHT DISTAL EXTERNAL ILIAC; BIOPSY:
- ONE BENIGN LYMPH NODE (0/1).
- 14) LYMPH NODE, RIGHT HYPOGASTRIC; EXCISION:
- TWO BENIGN LYMPH NODES (0/2).
- 15) LYMPH NODE, RIGHT OBTURATOR; EXCISION:
- THREE BENIGN LYMPH NODES (0/3).
- 16) LYMPH NODE, RIGHT PARA-AORTIC; EXCISION:
- TWO BENIGN LYMPH NODES (0/2).
- 17) LYMPH NODES, LEFT PARA-AORTIC; EXCISION:

** Continued on next page **

[page 3 of 3]
- FOUR BENIGN LYMPH NODES (0/4).

18) OMENTUM; OMENTECTOMY:
- BENIGN FIBROFATTY TISSUE.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

Source: NCI Genomic Data Commons file 13ed405e-a891-4447-9da6-2f13f0865b98 (TCGA-IR-A3LI.203CED2B-3E76-4539-9B52-D6F8FBF7E642.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).